Gene-level copy-number profile of tumor specimen ALCH-AE86-TTP1-A from ALCHEMIST case ALCH-AE86, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.3 years (27,513 days).
Specimen ALCH-AE86-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 92d1d6eb-61c4-4c32-bd85-63b24ea14f57.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE86-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/a02fb507-80af-45c1-b2bf-67504fcbf3b0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 4,001; copy number 2: 54,776; copy number 3: 53; copy number 4: 10; copy number 5: 8; copy number 8: 31; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:50,558,025–50,596,168, 2 genes: C3orf18, HEMK1.
- chr7:5,274,369–5,425,414, 4 genes: SLC29A4, TNRC18, AC093620.1, AC092171.1.
- chr9:66,721,158–66,745,929, 3 genes: ATP5F1AP10, SDR42E1P4, FKBP4P8.
- chr11:72,685,069–72,793,599, 5 genes (within-gene range 0–2): ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20.
- chr13:114,107,569–114,108,820, 1 gene (within-gene range 0–1): RASA3-IT1.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr17:18,377,778–18,389,647, 3 genes (within-gene range 0–2): EVPLL, AL353997.2, AL353997.3.
- chr19:43,646,095–43,670,547, 2 genes: PLAUR, RN7SL368P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 40 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:135,802,985–135,803,075, 1 gene, copy number 5: MIR5692C1.
- chr7:116,237,929–117,323,152, 38 genes, copy number 5–8 (within-gene range 2–8): AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2.
- chr14:105,664,633–105,669,843, 1 gene, copy number 9 (within-gene range 2–9): IGHGP.

Autosomal genes at a single copy (total copy number 1): 1,155. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
